Surgical pathology report (de-identified scan), TCGA case TCGA-CW-5581, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-5581-01A (Primary Tumor).

[page 1 of 2]
TCGA-CW-5581

Surgical Pathology

TISSUE DESCRIPTION:

Right kidney (235 grams, 12.2 x 6.8 x 6 cm) with 8.5 cm of attached ureter.

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 3 (of 4) renal cell carcinoma, clear cell type, forming a 6.3 x 5.2 x 4.4 cm mass located in the mid kidney and a separate .0.3 cm in diameter tumor nodule on the kidney surface. The renal vein is grossly free of tumor. The tumor does not involve the collecting system. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative. No renal hilar lymph nodes are identified. The adrenal gland is absent.

[page 2 of 2]
Surgical Pathology

TISSUE DESCRIPTION:

Right kidney (235 grams, 12.2 x 6.8 x 6 cm) with 8.5 cm of attached ureter.

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 3 (of 4) renal cell carcinoma, clear cell type, forming a 6.3 x 5.2 x 4.4 cm mass located in the mid kidney and a separate 0.3 cm in diameter tumor nodule on the kidney surface. The renal vein is grossly free of tumor. The tumor does not involve the collecting system. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative. No renal hilar lymph nodes are identified. The adrenal gland is absent.

Source: NCI Genomic Data Commons file 18583ee9-d0e8-4352-bbfd-5887d9ddc651 (TCGA-CW-5581.0C3F78B2-8B57-4966-8870-2214A1581214.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).